Somatic mutation profile of tumor specimen C3N-01844-03 (aliquot CPT0098430006) from CPTAC case C3N-01844, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 63.1 years (23,051 days).
Specimen C3N-01844-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ca19ee4-3c2f-44b9-bfc7-d2bb19cf14da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01844-71 (Blood Derived Normal), aliquot CPT0098450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6731f0df-4813-45c4-a2c5-676b78f17c31

The open-access MAF lists 274 somatic variants for this specimen: 171 protein-altering or splice-affecting, 94 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 160, Silent 94, Nonsense Mutation 8, Intron 4, 5'Flank 2, 3'UTR 2, Splice Region 2, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 242/363 reads (67%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PCSK5 | c.2772G>A p.W924* | Nonsense Mutation (SNP) | VAF 217/308 reads (70%) | hotspot (GDC flag); catalogued as rs1170804599, COSV70449546; called by muse, mutect2, varscan2
- ADAM32 | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 109/326 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.38); catalogued as rs766436330, COSV65947294; called by muse, mutect2, varscan2
- ANO3 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 134/390 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56811786, COSV99886479; called by muse, mutect2, varscan2
- ARSL | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 189/484 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV66966103; called by muse, mutect2, varscan2
- BARX2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 160/329 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as rs781552045; called by muse, mutect2, varscan2
- CACNA2D2 | c.1320G>A p.W440* | Nonsense Mutation (SNP) | VAF 236/445 reads (53%) | catalogued as rs1553729585; called by muse, mutect2, varscan2
- CD93 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 186/525 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs201896569; called by muse, varscan2
- CGNL1 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 128/318 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs770027591, COSV55566028; called by muse, mutect2, varscan2
- CHST6 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 155/322 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1278308755, CM091069; called by muse, mutect2, varscan2
- CNTNAP2 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs747014037, COSV62195484; called by muse, mutect2, varscan2
- COL5A1 | c.3287G>A p.G1096E | Missense Mutation (SNP) | VAF 265/404 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99057226; called by muse, mutect2, varscan2
- CTC1 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 139/298 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV59853181; called by muse, mutect2, varscan2
- CTU1 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 165/525 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70292451; called by muse, mutect2, varscan2
- CXCR1 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 130/365 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs372901871; called by muse, mutect2, varscan2
- CXCR2 | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 159/415 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as rs201271219, COSV59279953; called by muse, mutect2, varscan2
- DCC | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 112/366 reads (31%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.94); catalogued as COSV100499221; called by muse, mutect2, varscan2
- DSC1 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 83/309 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as rs745670805, COSV57141688; called by muse, mutect2, varscan2
- DSG3 | c.1820G>A p.R607K | Missense Mutation (SNP) | VAF 157/467 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0.011); catalogued as rs1476717664; called by muse, mutect2, varscan2
- DYTN | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 140/420 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV71752745; called by muse, mutect2
- ENPEP | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 156/517 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as rs767349194, COSV54450380; called by muse, mutect2, varscan2
- EPCAM | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55393270; called by muse, mutect2, varscan2
- EXOG | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 174/347 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs369327477; called by muse, mutect2, varscan2
- FGF17 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 87/280 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1219154111, COSV63925365; called by muse, mutect2, varscan2
- FHAD1 | c.3075G>A p.M1025I | Missense Mutation (SNP) | VAF 201/292 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1323138384; called by muse, mutect2, varscan2
- FKRP | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 168/436 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751676482, CM040822, COSV100586672, COSV59358628; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- H3C2 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.422); catalogued as rs990217604; called by muse, mutect2
- HCCS | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 83/305 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV58239004; called by muse, mutect2, varscan2
- HCRTR2 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV63795703; called by muse, mutect2, varscan2
- HTR3D | c.1097G>A p.G366E (on ENST00000382489 / NM_001163646.2; = p.G191E on NM_182537.3) | Missense Mutation (SNP) | VAF 136/590 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.096); catalogued as rs764286325, COSV61913836; called by muse, mutect2, varscan2
- IFNG | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as rs753611452, COSV57491582; called by muse, mutect2, varscan2
- IGBP1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 92/348 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as COSV100642963, COSV60555948; called by muse, varscan2
- IGSF1 | c.3457G>A p.E1153K | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV63839476; called by muse, mutect2, varscan2
- IL1RAP | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.266); catalogued as rs1182534655; called by muse, mutect2, varscan2
- IL37 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV54490005; called by muse, mutect2, varscan2
- KCNH5 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 257/382 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as rs372872099; called by muse, mutect2, varscan2
- KCNK6 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 186/626 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99649547; called by muse, mutect2, varscan2
- KDM2B | c.3166C>T p.P1056S | Missense Mutation (SNP) | VAF 125/389 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); catalogued as rs1555288523; called by muse, mutect2, varscan2
- KIAA1210 | c.2150C>T p.S717F | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99081429; called by muse, mutect2, varscan2
- KNTC1 | c.3689C>T p.P1230L | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61084868; called by muse, mutect2, varscan2
- LIFR | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 91/266 reads (34%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.834); catalogued as COSV54693785; called by muse, mutect2, varscan2
- LRCH1 | c.2002C>T p.H668Y | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs1255961017; called by muse, mutect2, varscan2
- LUZP2 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 63/236 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs369078244, COSV61198069; called by muse, mutect2, varscan2
- MAGEC2 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 160/392 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as rs771139214; called by muse, mutect2, varscan2
- MARCHF7 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 102/335 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52031941; called by muse, mutect2, varscan2
- NXPE4 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 139/259 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs572641123; called by muse, mutect2, varscan2
- OR1A2 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 145/274 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101126392; called by muse, mutect2, varscan2
- OR2M2 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 320/411 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV62897726, COSV62897788; called by muse, mutect2, varscan2
- PCDHA5 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 193/632 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.076); catalogued as rs782216490, COSV65351413; called by muse, mutect2, varscan2
- PCDHB4 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 142/438 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.118); catalogued as rs782017048; called by muse, mutect2, varscan2
- PCED1B | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 142/491 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.151); catalogued as rs765504758; called by muse, mutect2, varscan2
- PCK1 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 101/345 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.633); catalogued as rs372883844; called by muse, varscan2
- PDZD2 | c.8002G>A p.G2668R | Missense Mutation (SNP) | VAF 143/404 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779737696; called by muse, mutect2, varscan2
- PLK1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 130/383 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs1052549183; called by muse, mutect2, varscan2
- PNMA8B | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 157/503 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66537722; called by muse, mutect2, varscan2
- PRPF3 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 40/718 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as rs781846855, COSV61394553; called by muse, mutect2
- PTPRS | c.3032G>A p.R1011Q | Missense Mutation (SNP) | VAF 156/461 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.187); catalogued as rs1392874652; called by muse, mutect2, varscan2
- RAD50 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 90/259 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1400742267; called by muse, mutect2, varscan2
- RAD50 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104895044; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REG1B | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 63/236 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as rs752953261, COSV59304180; called by muse, mutect2, varscan2
- RELN | c.8761C>T p.L2921F | Missense Mutation (SNP) | VAF 131/345 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV59035219; called by muse, mutect2, varscan2
- RERG | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 108/322 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs748266862; called by muse, mutect2, varscan2
- RTL4 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 171/381 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0.045); catalogued as rs146678011, COSV61207335; called by muse, mutect2, varscan2
- RTL9 | c.4151C>T p.A1384V | Missense Mutation (SNP) | VAF 83/212 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.359); catalogued as COSV71825540; called by muse, mutect2, varscan2
- SCN9A | c.3524G>A p.G1175E (on ENST00000303354; = p.G1164E on NM_002977.3) | Missense Mutation (SNP) | VAF 98/303 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57600690; called by muse, mutect2, varscan2
- SLC13A1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 83/288 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs745484388; called by muse, mutect2, varscan2
- SLC17A5 | c.1468C>T p.H490Y | Missense Mutation (SNP) | VAF 79/277 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745377361, COSV63288784; called by muse, mutect2, varscan2
- SLC22A2 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 120/234 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs964360117; called by muse, mutect2, varscan2
- SLC26A3 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 71/226 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776026508, COSV60641544; called by muse, mutect2, varscan2
- SLC6A20 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 97/485 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.572); catalogued as COSV62071498; called by muse, mutect2, varscan2
- SLC9A5 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 104/227 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.309); catalogued as rs1446335127; called by muse, mutect2, varscan2
- SLIT2 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs201524539, COSV56572517; called by muse, mutect2, varscan2
- SMAP2 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 144/226 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV65532877; called by muse, mutect2, varscan2
- SMTNL1 | c.1153C>T p.P385S (on ENST00000399154; = p.P422S on NM_001105565.2) | Missense Mutation (SNP) | VAF 276/549 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866660047; called by muse, mutect2, varscan2
- STAG2 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54363157; called by muse, mutect2, varscan2
- TARM1 | c.167G>A p.R56Q (on ENST00000616041 / NM_001330650.1; = p.R48Q on NM_001135686.3) | Missense Mutation (SNP) | VAF 283/746 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as rs369139973; called by muse, mutect2, varscan2
- TEKT4 | c.1062G>A p.M354I | Missense Mutation (SNP) | VAF 95/343 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs1264011342; called by muse, mutect2, varscan2
- TENM2 | c.1048C>T p.R350C (on ENST00000518659 / NM_001122679.2; = p.R159C on NM_001080428.3) | Missense Mutation (SNP) | VAF 146/385 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs377232283, COSV69127367; called by muse, mutect2, varscan2
- TLE6 | c.1245G>A p.R415= (on ENST00000246112 / NM_001143986.2; = p.R292= on NM_024760.3) | Splice Region (SNP) | VAF 80/214 reads (37%) | catalogued as rs375998738; called by muse, mutect2, varscan2
- TMC6 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 141/486 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as rs1181277338; called by muse, mutect2, varscan2
- TMEM132B | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 156/374 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs267603370, COSV54752652; called by muse, mutect2, varscan2
- TMEM132C | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 121/371 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.27); catalogued as rs1348249766; called by muse, mutect2, varscan2
- TMEM52B | c.410G>A p.G137E (on ENST00000381923 / NM_001079815.1; = p.G117E on NM_153022.4) | Missense Mutation (SNP) | VAF 133/348 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV100046269; called by muse, mutect2, varscan2
- TNFRSF14 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 251/387 reads (65%) | SIFT tolerated (0.55); PolyPhen benign (0.168); catalogued as rs546999859, COSV100859158; called by muse, mutect2, varscan2
- TRIM69 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 108/346 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758996788; called by muse, mutect2, varscan2
- TSSK1B | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 115/397 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs61736967; called by muse, mutect2, varscan2
- TTN | c.46867G>A p.E15623K (on ENST00000591111; = p.E8199K on NM_003319.4) | Missense Mutation (SNP) | VAF 76/334 reads (23%) | PolyPhen benign (0.154); catalogued as rs566710566, COSV59940851; called by muse, mutect2, varscan2
- TTN | c.19744G>A p.E6582K (on ENST00000591111; = p.E5655K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 153/471 reads (32%) | PolyPhen possibly damaging (0.84); catalogued as COSV60245033; called by muse, mutect2, varscan2
- TTN | c.11257G>A p.E3753K (on ENST00000591111; = p.E3707K on NM_003319.4) | Missense Mutation (SNP) | VAF 134/450 reads (30%) | catalogued as rs397517830, CM1413163, COSV60378308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WWC3 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 67/324 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs1485612603, COSV66504215; called by muse, mutect2, varscan2
- ZFAT | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 171/454 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.278); catalogued as rs766044168, COSV100914769, COSV64737338; called by muse, mutect2, varscan2
- ZNF423 | c.2129C>T p.S710F (on ENST00000563137 / NM_001379286.1; = p.S702F on NM_015069.4) | Missense Mutation (SNP) | VAF 126/224 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV52175253; called by muse, mutect2, varscan2
- ZNF662 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 72/332 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as COSV60243270; called by muse, mutect2, varscan2
- ZNF75D | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs138085112, COSV66132565; called by muse, mutect2, varscan2
- ZNF835 | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 248/728 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.114); catalogued as COSV73379723; called by muse, mutect2
- ZSWIM8 | c.2454G>C p.K818N | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as rs1199352125; called by muse, mutect2, varscan2
- AC099489.1 | c.710G>C p.R237T | Missense Mutation (SNP) | VAF 172/745 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ACMSD | c.458A>T p.N153I | Missense Mutation (SNP) | VAF 106/294 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- ADAMTS1 | c.2470C>T p.Q824* | Nonsense Mutation (SNP) | VAF 143/420 reads (34%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 117/328 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS6 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3983C>T p.P1328L | Missense Mutation (SNP) | VAF 111/320 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASXL3 | c.5281G>A p.E1761K | Missense Mutation (SNP) | VAF 128/316 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AXIN2 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 186/705 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- BNC1 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 236/507 reads (47%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- C1RL | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 177/514 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CCDC166 | c.784A>G p.T262A | Missense Mutation (SNP) | VAF 206/568 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCDC171 | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 66/123 reads (54%) | SIFT tolerated (0.7); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- CELSR3 | c.9736C>T p.L3246F | Missense Mutation (SNP) | VAF 281/583 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COG5 | c.2167C>T p.P723S (on ENST00000347053 / NM_001379512.1; = p.P744S on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/309 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- COL11A1 | c.3236C>T p.P1079L | Missense Mutation (SNP) | VAF 228/348 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL6A6 | c.4910C>T p.A1637V | Missense Mutation (SNP) | VAF 111/427 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- EFR3A | c.233T>C p.M78T | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- ERAS | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 128/525 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- FAM120C | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 136/512 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); called by muse, varscan2
- FANCL | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 133/395 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- FSIP2 | c.8056G>C p.A2686P | Missense Mutation (SNP) | VAF 121/362 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- G3BP1 | c.1358A>C p.K453T | Missense Mutation (SNP) | VAF 147/428 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- HLCS | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 109/310 reads (35%) | called by muse, mutect2, varscan2
- HSP90B1 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 70/244 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ISLR | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 278/585 reads (48%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA2013 | c.1876T>C p.F626L | Missense Mutation (SNP) | VAF 320/459 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KRT83 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 225/590 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- LARGE2 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 80/350 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LARGE2 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 78/345 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAGEA3 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MARCHF10 | c.2232G>A p.M744I | Missense Mutation (SNP) | VAF 160/363 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MATN2 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 81/272 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- MIP | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 105/322 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMAB | c.614C>T p.T205I | Missense Mutation (SNP) | VAF 83/239 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MTIF2 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 86/292 reads (29%) | called by muse, mutect2, varscan2
- MYEOV | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 385/892 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MYO5C | c.2626C>T p.Q876* | Nonsense Mutation (SNP) | VAF 98/345 reads (28%) | called by muse, mutect2, varscan2
- NEUROD4 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 166/473 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- NLRP9 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 197/513 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR4K1 | c.907A>T p.N303Y | Missense Mutation (SNP) | VAF 132/366 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4X1 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 93/308 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OTOG | c.2548G>T p.G850* | Nonsense Mutation (SNP) | VAF 121/314 reads (39%) | called by muse, mutect2, varscan2
- OTOG | c.2549G>A p.G850E | Missense Mutation (SNP) | VAF 120/321 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHA8 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 194/585 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PI4KA | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 129/387 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIK3R4 | c.3544C>T p.P1182S | Missense Mutation (SNP) | VAF 98/415 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- PKP2 | c.2054T>G p.M685R | Missense Mutation (SNP) | VAF 95/328 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- PLEKHG4B | c.2059C>T p.L687F (on ENST00000283426; = p.L1043F on NM_052909.5) | Missense Mutation (SNP) | VAF 155/464 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRR30 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 130/390 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- PSD2 | c.977G>A p.G326D | Missense Mutation (SNP) | VAF 108/357 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PTK2 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- RABEP2 | c.1582T>C p.F528L | Missense Mutation (SNP) | VAF 80/261 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- RASGRP4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 148/498 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RFFL | c.455_464dup p.E157Rfs*4 | Frame Shift Ins (INS) | VAF 113/517 reads (22%) | called by mutect2, varscan2
- RTP1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 193/718 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- SLC22A14 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 332/650 reads (51%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- SLC7A7 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 165/248 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPDEF | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 117/363 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYTL2 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 100/220 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBC1D16 | c.183T>C p.G61= | Splice Region (SNP) | VAF 159/314 reads (51%) | called by muse, mutect2, varscan2
- TDRD6 | c.5005G>T p.E1669* | Nonsense Mutation (SNP) | VAF 12/251 reads (5%) | called by muse, mutect2
- THBS4 | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 138/362 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- TMEM237 | c.811C>T p.P271S (on ENST00000409883 / NM_001044385.3; = p.P263S on NM_152388.4) | Missense Mutation (SNP) | VAF 111/336 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM255A | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRMT5 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 213/304 reads (70%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- TSG101 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TTN | c.79024G>A p.D26342N (on ENST00000591111; = p.D18918N on NM_003319.4) | Missense Mutation (SNP) | VAF 133/359 reads (37%) | PolyPhen benign (0.221); called by muse, mutect2, varscan2
- UNC80 | c.1328T>A p.F443Y | Missense Mutation (SNP) | VAF 84/213 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- USP29 | c.2057C>A p.P686H | Missense Mutation (SNP) | VAF 150/436 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); called by muse, mutect2
- VWA3B | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 93/275 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- ZBTB33 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 47/353 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF117 | c.443G>T p.W148L | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF385C | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 298/609 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- ZNF577 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 182/530 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ZNF80 | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 156/570 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY10 | c.2190C>T p.S730= | Silent (SNP) | VAF 498/597 reads (83%) | called by muse, mutect2, varscan2
- ANKRD24 | c.3156G>A p.K1052= | Silent (SNP) | VAF 78/239 reads (33%) | catalogued as COSV99518037; called by muse, mutect2, varscan2
- ASPHD2 | c.462G>A p.R154= | Silent (SNP) | VAF 153/442 reads (35%) | catalogued as rs770275085; called by muse, mutect2, varscan2
- BRD8 | c.699C>T p.L233= (on ENST00000254900 / NM_139199.2; = p.L306= on NM_006696.4) | Silent (SNP) | VAF 103/318 reads (32%) | called by muse, mutect2, varscan2
- BRWD3 | c.3147G>A p.Q1049= | Silent (SNP) | VAF 44/160 reads (28%) | catalogued as COSV64744728; called by muse, mutect2, varscan2
- C17orf113 | c.1707C>T p.F569= | Silent (SNP) | VAF 126/469 reads (27%) | catalogued as rs962753832, COSV71536903; called by muse, mutect2, varscan2
- CACNA1C | c.2604G>A p.K868= | Silent (SNP) | VAF 101/359 reads (28%) | called by muse, mutect2, varscan2
- CCDC85A | c.747C>T p.S249= | Silent (SNP) | VAF 123/418 reads (29%) | called by muse, mutect2, varscan2
- CCRL2 | c.27G>A p.E9= | Silent (SNP) | VAF 106/461 reads (23%) | catalogued as COSV62193939; called by muse, mutect2, varscan2
- CD248 | c.2121C>T p.I707= | Silent (SNP) | VAF 160/674 reads (24%) | catalogued as rs770490701, COSV60936686; called by muse, mutect2, varscan2
- CHSY3 | c.1593C>T p.P531= | Silent (SNP) | VAF 100/292 reads (34%) | catalogued as COSV100520115; called by muse, mutect2, varscan2
- CNGA3 | c.1635C>T p.S545= | Silent (SNP) | VAF 146/444 reads (33%) | called by muse, mutect2, varscan2
- CSMD3 | c.1161C>T p.I387= | Silent (SNP) | VAF 133/394 reads (34%) | called by muse, mutect2, varscan2
- DLL3 | c.1176G>A p.L392= | Silent (SNP) | VAF 175/511 reads (34%) | catalogued as rs765401126; called by muse, mutect2, varscan2
- DNAH5 | c.1179C>T p.I393= | Silent (SNP) | VAF 40/127 reads (31%) | catalogued as COSV54207534, COSV54242204; called by muse, mutect2, varscan2
- DNER | c.1953C>T p.I651= | Silent (SNP) | VAF 106/346 reads (31%) | catalogued as COSV100519137, COSV59165708; called by muse, mutect2, varscan2
- ELK1 | c.243C>T p.F81= | Silent (SNP) | VAF 97/399 reads (24%) | catalogued as rs763088656, COSV55953832; called by muse, mutect2, varscan2
- EPHA6 | c.2547G>A p.E849= (on ENST00000389672 / NM_001080448.3; = p.E241= on NM_173655.4) | Silent (SNP) | VAF 142/517 reads (27%) | called by muse, mutect2, varscan2
- FAM47A | c.1629C>T p.L543= | Silent (SNP) | VAF 177/503 reads (35%) | catalogued as COSV60499715; called by muse, mutect2, varscan2
- FAT2 | c.3057C>T p.I1019= | Silent (SNP) | VAF 130/423 reads (31%) | catalogued as rs147733173, COSV99943322; called by muse, mutect2, varscan2
- FKBP9 | c.1614G>A p.V538= | Silent (SNP) | VAF 46/492 reads (9%) | called by muse, mutect2
- FRMPD3 | c.4017G>A p.R1339= | Silent (SNP) | VAF 179/397 reads (45%) | catalogued as rs1232963780; called by muse, mutect2, varscan2
- FYB1 | c.1107G>A p.T369= | Silent (SNP) | VAF 95/278 reads (34%) | catalogued as rs373238246; called by muse, mutect2, varscan2
- GABRA5 | c.609C>T p.Y203= | Silent (SNP) | VAF 68/264 reads (26%) | catalogued as rs751197696, COSV59475337; called by muse, mutect2, varscan2
- GHDC | c.420G>A p.K140= | Silent (SNP) | VAF 116/460 reads (25%) | called by muse, mutect2, varscan2
- GLYAT | c.438C>T p.F146= | Silent (SNP) | VAF 263/484 reads (54%) | catalogued as rs975606397, COSV53540521; called by muse, mutect2, varscan2
- HEPH | c.3288G>T p.L1096= (on ENST00000343002; = p.L829= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/426 reads (8%) | called by muse, mutect2
- HNRNPUL1 | c.1212C>T p.P404= | Silent (SNP) | VAF 152/425 reads (36%) | catalogued as rs867126206, COSV54565320; called by muse, mutect2, varscan2
- HUWE1 | c.1662C>T p.L554= | Silent (SNP) | VAF 75/218 reads (34%) | catalogued as rs781881715; called by muse, varscan2
- ICAM4 | c.81G>A p.R27= | Silent (SNP) | VAF 162/491 reads (33%) | catalogued as COSV53427347; called by muse, mutect2, varscan2
- IFNGR2 | c.477C>T p.F159= | Silent (SNP) | VAF 163/470 reads (35%) | catalogued as COSV51640185; called by muse, mutect2, varscan2
- IPO13 | c.1425C>T p.S475= | Silent (SNP) | VAF 237/320 reads (74%) | catalogued as rs375735197; called by muse, mutect2, varscan2
- ITGA6 | c.54C>T p.S18= | Silent (SNP) | VAF 121/352 reads (34%) | catalogued as rs1419807933; called by muse, mutect2, varscan2
- KCND3 | c.1920G>A p.T640= | Silent (SNP) | VAF 343/533 reads (64%) | catalogued as rs1167459243, COSV56186881; called by muse, mutect2, varscan2
- KIAA1755 | c.1059G>A p.R353= | Silent (SNP) | VAF 128/398 reads (32%) | called by muse, mutect2, varscan2
- KIF17 | c.750C>T p.T250= | Silent (SNP) | VAF 328/459 reads (71%) | catalogued as rs763837492; called by muse, mutect2, varscan2
- KRTAP26-1 | c.345G>A p.Q115= | Silent (SNP) | VAF 95/347 reads (27%) | catalogued as rs267606097, COSV62128926; called by muse, mutect2, varscan2
- MGAM | c.961C>T p.L321= | Silent (SNP) | VAF 93/319 reads (29%) | catalogued as COSV101516372; called by muse, mutect2, varscan2
- MUC16 | c.38634G>A p.R12878= | Silent (SNP) | VAF 70/253 reads (28%) | catalogued as COSV67480366; called by muse, mutect2, varscan2
- MYBPC1 | c.2550C>T p.I850= (on ENST00000550270 / NM_206820.2; = p.I857= on NM_002465.4) | Silent (SNP) | VAF 104/329 reads (32%) | called by muse, mutect2, varscan2
- MYH13 | c.2121G>A p.R707= | Silent (SNP) | VAF 115/255 reads (45%) | catalogued as COSV52842839; called by muse, mutect2, varscan2
- MYO7A | c.4695G>A p.T1565= | Silent (SNP) | VAF 163/956 reads (17%) | catalogued as rs397516313, COSV101289192, COSV68684977; ClinVar: likely benign; called by muse, mutect2, varscan2
- NACA2 | c.543G>A p.V181= | Silent (SNP) | VAF 316/615 reads (51%) | catalogued as rs878996246, COSV71713093, COSV71713201; called by muse, mutect2, varscan2
- NCOA5 | c.345C>T p.D115= | Silent (SNP) | VAF 74/229 reads (32%) | called by muse, mutect2, varscan2
- NIN | c.843A>C p.T281= | Silent (SNP) | VAF 206/308 reads (67%) | called by muse, mutect2, varscan2
- NPAS4 | c.639C>T p.F213= | Silent (SNP) | VAF 157/764 reads (21%) | catalogued as COSV60649429; called by muse, mutect2, varscan2
- OR13C4 | c.405C>T p.I135= | Silent (SNP) | VAF 282/432 reads (65%) | called by muse, mutect2, varscan2
- OR1L4 | c.249G>A p.L83= | Silent (SNP) | VAF 206/306 reads (67%) | called by muse, varscan2
- OR4C5 | c.45C>T p.I15= | Silent (SNP) | VAF 83/270 reads (31%) | catalogued as COSV100164375; called by muse, mutect2, varscan2
- OR52M1 | c.312C>T p.F104= | Silent (SNP) | VAF 136/415 reads (33%) | catalogued as rs530863910; called by muse, mutect2, varscan2
- PABPC3 | c.207G>A p.L69= | Silent (SNP) | VAF 135/401 reads (34%) | called by muse, mutect2, varscan2
- PAH | c.909C>T p.S303= | Silent (SNP) | VAF 62/211 reads (29%) | catalogued as COSV61020493; called by muse, mutect2, varscan2
- PCARE | c.3468C>T p.L1156= | Silent (SNP) | VAF 168/483 reads (35%) | catalogued as rs752782141, COSV59052920; called by muse, mutect2, varscan2
- PCDHA5 | c.1437G>A p.R479= | Silent (SNP) | VAF 195/634 reads (31%) | catalogued as rs1282468969, COSV65354827; called by muse, mutect2, varscan2
- PCDHA8 | c.1374C>T p.P458= | Silent (SNP) | VAF 226/641 reads (35%) | catalogued as COSV65334968; called by muse, mutect2, varscan2
- PCSK2 | c.1302C>T p.V434= | Silent (SNP) | VAF 129/384 reads (34%) | catalogued as rs141714677, COSV99359783; called by muse, mutect2, varscan2
- PHKA1 | c.1188G>A p.G396= | Silent (SNP) | VAF 112/390 reads (29%) | called by muse, mutect2, varscan2
- PIK3CG | c.906G>A p.E302= | Silent (SNP) | VAF 118/373 reads (32%) | called by muse, mutect2, varscan2
- PLCB2 | c.1980C>T p.F660= | Silent (SNP) | VAF 103/335 reads (31%) | catalogued as COSV53031144; called by muse, mutect2, varscan2
- PNLIPRP3 | c.507G>A p.L169= | Silent (SNP) | VAF 26/284 reads (9%) | catalogued as COSV100982398, COSV65049682; called by muse, mutect2
- PPFIA2 | c.261C>T p.S87= | Silent (SNP) | VAF 96/265 reads (36%) | catalogued as COSV61036063; called by muse, mutect2, varscan2
- PRR30 | c.60C>T p.P20= | Silent (SNP) | VAF 130/388 reads (34%) | called by muse, mutect2, varscan2
- RAB11FIP4 | c.1626C>T p.L542= | Silent (SNP) | VAF 116/479 reads (24%) | catalogued as rs866330533, COSV57932839; called by muse, mutect2, varscan2
- RAD17 | c.1743C>T p.I581= (on ENST00000380774 / NM_133339.2; = p.I570= on NM_002873.1) | Silent (SNP) | VAF 67/208 reads (32%) | called by muse, mutect2, varscan2
- RIBC2 | c.531C>T p.N177= | Silent (SNP) | VAF 28/284 reads (10%) | catalogued as rs762701208; called by muse, mutect2
- ROS1 | c.2490G>A p.G830= | Silent (SNP) | VAF 82/134 reads (61%) | catalogued as rs1192848015, COSV63857718; called by muse, mutect2, varscan2
- RP1 | c.4953C>T p.T1651= | Silent (SNP) | VAF 114/344 reads (33%) | catalogued as COSV55129371; called by muse, mutect2
- SCARF2 | c.1879C>T p.L627= | Silent (SNP) | VAF 216/590 reads (37%) | called by muse, mutect2, varscan2
- SCGN | c.507G>A p.L169= | Silent (SNP) | VAF 85/293 reads (29%) | catalogued as COSV100618814; called by muse, mutect2, varscan2
- SCN11A | c.420C>T p.I140= | Silent (SNP) | VAF 96/401 reads (24%) | called by muse, mutect2, varscan2
- SGK2 | c.561G>A p.R187= | Silent (SNP) | VAF 109/335 reads (33%) | called by muse, mutect2, varscan2
- SLC6A16 | c.297C>T p.V99= | Silent (SNP) | VAF 201/580 reads (35%) | called by muse, mutect2, varscan2
- SRCIN1 | c.2745C>T p.A915= (on ENST00000621492; = p.A881= on NM_025248.3) | Silent (SNP) | VAF 302/613 reads (49%) | called by muse, mutect2, varscan2
- STK40 | c.552G>A p.V184= | Silent (SNP) | VAF 176/258 reads (68%) | catalogued as rs151238337; called by muse, mutect2, varscan2
- TBC1D2 | c.2535C>T p.I845= (on ENST00000465784 / NM_001267571.2; = p.I834= on NM_018421.4) | Silent (SNP) | VAF 174/264 reads (66%) | called by muse, mutect2, varscan2
- TGM5 | c.1746C>T p.S582= (on ENST00000220420 / NM_201631.4; = p.S500= on NM_004245.4) | Silent (SNP) | VAF 73/284 reads (26%) | catalogued as COSV55012704; called by muse, mutect2, varscan2
- TIMM13 | c.90C>T p.I30= | Silent (SNP) | VAF 99/300 reads (33%) | catalogued as rs755241285; called by muse, mutect2, varscan2
- TMEM168 | c.339C>T p.S113= | Silent (SNP) | VAF 100/311 reads (32%) | catalogued as COSV100454780; called by muse, mutect2, varscan2
- TNFRSF14 | c.495C>T p.C165= | Silent (SNP) | VAF 249/385 reads (65%) | catalogued as COSV63185963; called by muse, mutect2, varscan2
- TRAPPC13 | c.174T>G p.V58= | Silent (SNP) | VAF 81/255 reads (32%) | called by muse, mutect2, varscan2
- TRERF1 | c.591C>T p.I197= | Silent (SNP) | VAF 151/404 reads (37%) | called by muse, mutect2, varscan2
- TSG101 | c.276T>C p.T92= | Silent (SNP) | VAF 82/280 reads (29%) | catalogued as rs778604781; called by muse, mutect2, varscan2
- TUBGCP4 | c.762G>A p.L254= | Silent (SNP) | VAF 69/244 reads (28%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.2607C>T p.F869= | Silent (SNP) | VAF 90/354 reads (25%) | catalogued as rs570717920; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP19 | c.2682C>T p.S894= | Silent (SNP) | VAF 211/735 reads (29%) | called by muse, mutect2, varscan2
- UTP15 | c.606C>T p.S202= | Silent (SNP) | VAF 111/327 reads (34%) | catalogued as rs368165894; called by muse, mutect2, varscan2
- WDR87 | c.6963G>A p.L2321= | Silent (SNP) | VAF 118/368 reads (32%) | called by muse, mutect2, varscan2
- WDR87 | c.1491G>C p.L497= | Silent (SNP) | VAF 108/269 reads (40%) | called by muse, mutect2, varscan2
- XPNPEP1 | c.1035C>T p.I345= | Silent (SNP) | VAF 54/107 reads (50%) | called by muse, mutect2, varscan2
- YME1L1 | c.894C>T p.F298= (on ENST00000326799 / NM_139312.3; = p.F241= on NM_014263.4) | Silent (SNP) | VAF 113/228 reads (50%) | catalogued as rs773737982, COSV58758470; called by muse, mutect2, varscan2
- ZBTB40 | c.444C>T p.I148= | Silent (SNP) | VAF 235/371 reads (63%) | called by muse, mutect2, varscan2
- ZNF284 | c.1149C>T p.S383= | Silent (SNP) | VAF 84/274 reads (31%) | called by muse, mutect2, varscan2
- ZNF469 | c.9813C>T p.A3271= (on ENST00000437464; = p.A3299= on NM_001367624.2) | Silent (SNP) | VAF 169/325 reads (52%) | called by muse, mutect2, varscan2
- ZNF804A | c.2658C>T p.L886= | Silent (SNP) | VAF 125/370 reads (34%) | catalogued as COSV100167100; called by muse, mutect2, varscan2
- ADRA1A | c.884-8665A>G | Intron (SNP) | VAF 109/341 reads (32%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822711 G>A | 5'Flank (SNP) | VAF 78/254 reads (31%) | called by muse, mutect2, varscan2
- ATP11A | c.*978C>T | 3'UTR (SNP) | VAF 112/362 reads (31%) | catalogued as rs1448055903; called by muse, mutect2, varscan2
- ATP6V1G3 | c.82+3880G>A | Intron (SNP) | VAF 152/224 reads (68%) | called by muse, mutect2, varscan2
- COL6A5 | c.*545C>T | 3'UTR (SNP) | VAF 133/275 reads (48%) | catalogued as rs1052591728, COSV55195209; called by muse, mutect2, varscan2
- MYL3 | chr3:46832963 C>T | 3'Flank (SNP) | VAF 95/379 reads (25%) | called by muse, mutect2, varscan2
- OR2T2 | chr1:248441587 G>C | 5'Flank (SNP) | VAF 617/1519 reads (41%) | called by muse, mutect2, varscan2
- PRMT2 | c.654+2154C>T | Intron (SNP) | VAF 183/560 reads (33%) | called by muse, mutect2, varscan2
- UNC13B | c.762-3271G>A | Intron (SNP) | VAF 92/349 reads (26%) | called by muse, mutect2, varscan2
